Somatic mutation profile of tumor specimen TCGA-QC-A6FX-01A (aliquot TCGA-QC-A6FX-01A-11D-A32I-09) from TCGA case TCGA-QC-A6FX, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Undifferentiated sarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of trunk, NOS; Age at diagnosis: 68.8 years (25,113 days).
Specimen TCGA-QC-A6FX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dfe9c078-daf3-4f07-82c8-0c9f39581592.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QC-A6FX-10B (Blood Derived Normal), aliquot TCGA-QC-A6FX-10B-01D-A32I-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ad4593eb-6dd1-4c06-a6e0-dbdcf8728437

The open-access MAF lists 39 somatic variants for this specimen: 30 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 24, Silent 9, Splice Site 2, Nonsense Mutation 2, Frame Shift Del 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.725G>C p.C242S | Missense Mutation (SNP) | VAF 35/40 reads (88%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912655, CM910618, COSV52661189, COSV52677418, COSV52689710; called by muse, mutect2, varscan2
- CDH12 | c.527-1G>T p.X176_splice | Splice Site (SNP) | VAF 22/75 reads (29%) | catalogued as COSV101202872; called by muse, mutect2, varscan2
- CEACAM18 | c.924C>G p.Y308* | Nonsense Mutation (SNP) | VAF 17/75 reads (23%) | catalogued as COSV101140484, COSV99070390; called by muse, mutect2, varscan2
- COL14A1 | c.2873G>T p.R958M | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.104); catalogued as COSV99919835; called by muse, mutect2
- DCAF4L2 | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV60478305; called by muse, mutect2, varscan2
- FRMPD4 | c.3113C>T p.A1038V | Missense Mutation (SNP) | VAF 13/18 reads (72%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as rs1210384543, COSV101043330; called by muse, mutect2, varscan2
- ID3 | c.301-2A>G p.X101_splice | Splice Site (SNP) | VAF 27/61 reads (44%) | catalogued as COSV101000779; called by muse, mutect2, varscan2
- ITGA10 | c.1007A>G p.N336S | Missense Mutation (SNP) | VAF 29/34 reads (85%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.842); catalogued as rs782593160, COSV100994970; called by muse, mutect2, varscan2
- MUC5B | c.12695C>T p.P4232L | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs373850484; called by muse, mutect2, varscan2
- NPAP1 | c.2518T>A p.F840I | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.019); catalogued as COSV100275556, COSV100275819; called by muse, mutect2, varscan2
- PCDH1 | c.851C>T p.S284F | Missense Mutation (SNP) | VAF 38/63 reads (60%) | SIFT tolerated (0.06); PolyPhen benign (0.067); catalogued as rs1449250053, COSV99746500; called by muse, mutect2, varscan2
- PHRF1 | c.1999C>G p.L667V (on ENST00000264555 / NM_001286581.2; = p.L666V on NM_020901.4) | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs1287924966, COSV99212124; called by muse, mutect2
- PPFIA2 | c.2288G>C p.R763P | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.378); catalogued as COSV100334354, COSV61020021; called by muse, mutect2, varscan2
- RNF150 | c.526G>A p.G176R | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100153788; called by muse, mutect2, varscan2
- RSPH4A | c.1498C>G p.L500V | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); catalogued as rs779913947, COSV99994200; called by muse, varscan2
- RYR2 | c.4177A>C p.T1393P | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.205); catalogued as COSV100771649, COSV63669360; called by muse, mutect2, varscan2
- SERBP1 | c.322C>T p.R108* | Nonsense Mutation (SNP) | VAF 25/30 reads (83%) | catalogued as COSV100769134; called by muse, mutect2, varscan2
- SIPA1 | c.1343C>T p.T448I | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as rs370772263; called by muse, mutect2, varscan2
- SLCO4A1 | c.797C>T p.A266V | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.948); catalogued as COSV99414877; called by muse, mutect2, varscan2
- STRC | c.4805G>A p.R1602Q | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.91); catalogued as rs562392825, COSV55853737; called by mutect2, varscan2
- SUPT16H | c.1679C>T p.S560F | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99360010; called by muse, mutect2
- TLR3 | c.1378G>A p.E460K | Missense Mutation (SNP) | VAF 19/23 reads (83%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.775); catalogued as rs144550375; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TMEM135 | c.938G>A p.G313D | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.961); catalogued as COSV100449868; called by muse, mutect2, varscan2
- TRDN | c.115G>A p.D39N | Missense Mutation (SNP) | VAF 42/83 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100522573, COSV62121453; called by muse, mutect2, varscan2
- TTC30B | c.382G>A p.D128N | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV101282799; called by muse, mutect2, varscan2
- UBE2O | c.3370G>C p.E1124Q | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV100039445; called by muse, mutect2, varscan2
- ZNF257 | c.665C>G p.T222S | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV101448125; called by muse, mutect2, varscan2
- CFAP74 | c.773C>T p.A258V | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.844); called by muse, varscan2
- RAB38 | c.445del p.E149Sfs*5 | Frame Shift Del (DEL) | VAF 10/58 reads (17%) | called by mutect2, pindel, varscan2
- RABEP1 | c.621_632del p.D207_K210del | In Frame Del (DEL) | VAF 28/86 reads (33%) | called by mutect2, pindel, varscan2
- CDH8 | c.2361C>T p.G787= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as rs200638903, COSV54848805, COSV54878827; called by muse, mutect2, varscan2
- KIF17 | c.255C>T p.G85= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as COSV99929314; called by muse, mutect2, varscan2
- KRTAP10-12 | c.624C>A p.R208= | Silent (SNP) | VAF 3/22 reads (14%) | catalogued as COSV100554443; called by muse, mutect2
- MAGEL2 | c.1938G>A p.E646= | Silent (SNP) | VAF 15/20 reads (75%) | catalogued as rs1426950963, COSV100046043; called by muse, mutect2, varscan2
- TIAM1 | c.1659C>T p.H553= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as rs1441766230, COSV99736703; called by muse, mutect2
- TRAV12-2 | c.273G>A p.Q91= | Silent (SNP) | VAF 15/77 reads (19%) | called by muse, mutect2, varscan2
- TRPM2 | c.4209G>A p.K1403= | Silent (SNP) | VAF 6/10 reads (60%) | catalogued as rs993113331, COSV100309043; called by mutect2, varscan2
- UNC79 | c.1083T>A p.L361= (on ENST00000393151 / NM_001346218.2; = p.L184= on NM_020818.5) | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as COSV99828607; called by muse, mutect2, varscan2
- XPO6 | c.3036G>C p.L1012= | Silent (SNP) | VAF 13/62 reads (21%) | catalogued as COSV100485168; called by muse, mutect2, varscan2
